Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1JD, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1JD-01A (Primary Tumor).

[page 1 of 2]
ICD-0-3

Carcinoma, infiltrating ductal, NOS 8500/3

Site: breast C50.9
NOS page 1 / 2

3/11/11 *aw*

Department of Cancer Pathology

copy No.

Date:

Examination: **Histopathological examination**

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: **1. Total organ resection – left breast and axillary tissue**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: **up to 8 working days**

Clinical diagnosis: **Cancer of the left breast - outer upper quad.**

Examination performed on

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei.

Progesterone receptors found in 10-75% of neoplastic cell nuclei.

HER2 protein stained with HercepTest™ by DAKO.

Negative reaction in invasive cancerous cells (Score = 1+)

Compliance validated by:

Examination performed on:

Macroscopic description:

Left breast sized 19 x 18 x 5 cm removed along with axillary tissues sized 11 x 4.5 x 1.5 cm and a 19 x 10 cm skin flap. Weight 620 g.

Tumour sized 2.8 x 1.5 x 2.5 cm on the border of upper quadrants, 4.5 cm from the upper boundary, 0.2 cm from the base and 1.0 cm from the skin.

Another tumour sized 0.5 x 0.7 x 0.5 cm found 1.5 cm away from the first one (margins: lower boundary – 10 cm; base – 0.1 cm; skin – 3.5 cm).

Diagnostic Discrepancy		☒

[page 2 of 2]
Microscopic description:

Both tumours showing similar pattern.

Carcinoma ductale invasivum bifocal - NHG2 (2 + 3 +1/7 mitoses/10 HPF, visual area diameter 0.55 mm).

Foci of carcinoma ductale in situ DCIS found within the tumour (solid and cribrate type with high nuclear atypia and comedo necrosis, 5% of the tumour).

Reactio lymphocytaria peritumoralis.

Mamilla sine laesionibus.

Glandular tissue showing mastopathia fibrosa et cystica.

AXILLARY LYMPH NODES:

Metastases carcinomatosae in lymphonodis No III/XIV.

Infiltratio capsulae lymphonodis et telae perinodalis.

page 2 / 2

Examination No.:

Patient: XXX

PESEL: XXX

Gender: F

Examination performed on

Histopathological diagnosis:

Carcinoma ductale invasivum bifocale mammae sinistrae. Invasive bifocal ductal carcinoma of the left breast.

Metastases carcinomatosae in lymphonodis axillae No. III/XIV. Cancer metastases in axillary lymph nodes No. III/XIV.

(NHG2, pT2, pN1a).

Compliance validated by: ;

Source: NCI Genomic Data Commons file 180899e9-3ba6-4918-ba7f-6e71cc8e3e0d (TCGA-D8-A1JD.332880ED-FE4E-4EE4-9E96-0A61BFCCA27E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).